Somatic mutation profile of tumor specimen TCGA-OR-A5LS-01A (aliquot TCGA-OR-A5LS-01A-11D-A29I-10) from TCGA case TCGA-OR-A5LS, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 34.7 years (12,663 days).
Specimen TCGA-OR-A5LS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ed5dd1a5-631a-4444-b0aa-e443a488c77a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5LS-10A (Blood Derived Normal), aliquot TCGA-OR-A5LS-10A-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/15397f09-6c3a-450c-84d7-e837ef36a94b

The open-access MAF lists 11 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 7, Nonsense Mutation 2, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IFRD2 | c.1496G>A p.R499Q | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782114599, COSV100269214; called by muse, mutect2
- SI | c.787C>T p.R263* | Nonsense Mutation (SNP) | VAF 86/193 reads (45%) | catalogued as rs756977393, COSV52281667; called by muse, mutect2, varscan2
- ARHGAP32 | c.1177A>G p.T393A (on ENST00000310343 / NM_001378025.1; = p.T44A on NM_014715.4) | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- GNL2 | c.785C>A p.T262N | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.836); called by muse, mutect2
- HIVEP3 | c.2602G>T p.D868Y | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- SDCBP2 | c.538A>G p.I180V (on ENST00000339987 / NM_001199784.1; = p.I95V on NM_015685.5) | Missense Mutation (SNP) | VAF 66/214 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- SEC24D | c.2607G>C p.Q869H | Missense Mutation (SNP) | VAF 68/336 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SLC27A5 | c.1807C>G p.P603A | Missense Mutation (SNP) | VAF 70/167 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SLCO4C1 | c.1306C>T p.Q436* | Nonsense Mutation (SNP) | VAF 12/311 reads (4%) | called by muse, mutect2
- CDH8 | c.1227G>C p.V409= | Silent (SNP) | VAF 86/227 reads (38%) | called by muse, mutect2, varscan2
- FRMPD3 | c.5289A>G p.Q1763= | Silent (SNP) | VAF 53/167 reads (32%) | catalogued as rs367997323; called by mutect2, varscan2
